Somatic mutation profile of tumor specimen MP2PRT-PAULWI-TMP1-A (aliquot MP2PRT-PAULWI-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAULWI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,414 days).
Specimen MP2PRT-PAULWI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 193610fd-45cd-4db7-8f51-ea58ac852b2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAULWI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAULWI-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca69652d-00d6-49ff-9db7-b6681c3dc08d

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 14, Silent 5, Nonsense Mutation 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.57G>C p.L19F | Missense Mutation (SNP) | VAF 79/249 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs121913538, CM155383, COSV55502103, COSV55521217; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANTXRL | c.1880C>G p.S627* | Nonsense Mutation (SNP) | VAF 69/205 reads (34%) | catalogued as rs1238372491; called by muse, mutect2, varscan2
- FSIP2 | c.15251C>T p.S5084L | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.514); catalogued as rs773888377; called by muse, mutect2, varscan2
- LRP1B | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 120/309 reads (39%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.043); catalogued as rs765975433; called by muse, mutect2, varscan2
- NDN | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 101/336 reads (30%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.009); catalogued as COSV100086701, COSV59359657; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 92/258 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKN | c.240G>C p.M80I | Missense Mutation (SNP) | VAF 100/303 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100629254; called by muse, mutect2, varscan2
- RADX | c.2122C>T p.R708W | Missense Mutation (SNP) | VAF 101/143 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as rs775530156, COSV65319126; called by muse, mutect2, varscan2
- TXNRD3 | c.1368G>C p.K456N | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV73120024; called by muse, mutect2, varscan2
- ZNF236 | c.2410G>A p.E804K | Missense Mutation (SNP) | VAF 120/366 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as rs773110046, COSV53483851; called by muse, mutect2, varscan2
- EYS | c.5027C>T p.S1676L | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- GULP1 | c.569T>A p.L190* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- IGHV1-69 | c.350_351insGGGGGGGAG | In Frame Ins (INS) | VAF 11/67 reads (16%) | called by mutect2, pindel, varscan2
- KIF15 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC38A6 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SZT2 | c.9718C>G p.L3240V (on ENST00000634258 / NM_001365999.1; = p.L3183V on NM_015284.4) | Missense Mutation (SNP) | VAF 15/437 reads (3%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2
- WASF3 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 75/226 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- BBOF1 | c.129G>A p.L43= | Silent (SNP) | VAF 14/220 reads (6%) | catalogued as rs1239002687; called by muse, mutect2
- CDH1 | c.2355C>T p.N785= | Silent (SNP) | VAF 133/354 reads (38%) | catalogued as rs375988871, COSV55737427; ClinVar: likely benign; called by muse, mutect2, varscan2
- DES | c.180G>A p.S60= | Silent (SNP) | VAF 192/565 reads (34%) | called by muse, mutect2, varscan2
- KCNJ3 | c.1248C>T p.L416= | Silent (SNP) | VAF 90/295 reads (31%) | catalogued as COSV54534573; called by muse, mutect2, varscan2
- SFRP4 | c.573C>T p.L191= | Silent (SNP) | VAF 71/254 reads (28%) | called by muse, mutect2, varscan2
